Somatic mutation profile of tumor specimen TCGA-DD-A73C-01A (aliquot TCGA-DD-A73C-01A-12D-A33K-10) from TCGA case TCGA-DD-A73C, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 65.1 years (23,782 days).
Specimen TCGA-DD-A73C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22785f9b-389e-495b-83df-498120792123.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A73C-10A (Blood Derived Normal), aliquot TCGA-DD-A73C-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b75bb27-7629-47da-bf57-236e8aca626f

The open-access MAF lists 97 somatic variants for this specimen: 71 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 24, Frame Shift Del 6, In Frame Del 3, Nonsense Mutation 3, Splice Site 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMDEC1 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1440121047, COSV56476835; called by muse, mutect2, varscan2
- AP3M1 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs1487440243, COSV62332179; called by muse, mutect2, varscan2
- APLP2 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.146); catalogued as COSV99599968; called by muse, mutect2
- ARID3A | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV55045905; called by muse, mutect2, varscan2
- ARL9 | c.521C>A p.S174* (on ENST00000640821 / NM_001363794.2; = p.S32* on NM_206919.2) | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV63991453; called by muse, mutect2, varscan2
- ATG2B | c.3805A>C p.S1269R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs529500826, COSV55891674; called by muse, mutect2, varscan2
- ATP12A | c.2776A>G p.R926G | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54520474; called by muse, mutect2, varscan2
- CAAP1 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.79); catalogued as rs745984338, COSV61701373; called by muse, mutect2, varscan2
- CAVIN1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV63812492; called by muse, mutect2, varscan2
- CEP350 | c.9282G>T p.E3094D | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.119); catalogued as COSV62607805; called by muse, mutect2, varscan2
- CILP | c.3491G>T p.R1164L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV56026804; called by muse, mutect2, varscan2
- CNKSR2 | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54262938; called by muse, mutect2
- CNOT10 | c.1674A>C p.K558N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV59394134; called by muse, mutect2, varscan2
- CPS1 | c.3229G>C p.G1077R | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51819845; called by muse, mutect2, varscan2
- CUL5 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs1278845366, COSV67609810; called by muse, mutect2, varscan2
- DHX57 | c.3639A>G p.I1213M | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.145); catalogued as COSV54889351, COSV54892194; called by muse, mutect2
- DMBT1 | c.2465G>C p.C822S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV57554119; called by muse, mutect2, varscan2
- EFCAB13 | c.378T>A p.N126K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV58951279; called by muse, mutect2, varscan2
- EHMT2 | c.668-2A>T p.X223_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV64997471; called by muse, mutect2, varscan2
- EZH1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV70550292; called by muse, mutect2, varscan2
- FBN2 | c.6970C>T p.P2324S | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV52534858; called by muse, mutect2, varscan2
- FCRL1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as COSV63823896; called by muse, mutect2, varscan2
- GOLGB1 | c.7529A>T p.E2510V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61469184; called by muse, mutect2, varscan2
- GPC3 | c.618A>C p.K206N | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as COSV63669375; called by muse, mutect2
- HEATR6 | c.3467G>T p.G1156V | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs761191743, COSV51747830; called by muse, mutect2, varscan2
- HNF1A | c.326+2T>A p.X109_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV57465613; called by muse, mutect2, varscan2
- INSRR | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs747196691, COSV63876137; called by muse, mutect2, varscan2
- IRF3 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV55864215; called by muse, mutect2, varscan2
- KATNAL2 | c.759G>T p.W253C (on ENST00000356157 / NM_001353899.1; = p.W181C on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55305073; called by muse, mutect2, varscan2
- KMT2E | c.5250T>G p.F1750L | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV57577664; called by muse, mutect2, varscan2
- KPTN | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57646014; called by muse, mutect2, varscan2
- L3MBTL1 | c.1279A>T p.S427C (on ENST00000418998 / NM_001377303.1; = p.S337C on NM_015478.7) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV64229355; called by muse, mutect2
- LRP4 | c.5431G>T p.E1811* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV66137720; called by muse, mutect2, varscan2
- LRRN1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1300200167, COSV60012895; called by muse, mutect2
- MFSD8 | c.883A>G p.M295V | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs1429999400, COSV56552388; called by muse, mutect2
- NHS | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV66279882; called by muse, mutect2, varscan2
- ODF3B | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99329716; called by muse, mutect2
- OPRM1 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV57672236; called by muse, mutect2, varscan2
- OPRM1 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100002074; called by muse, mutect2, varscan2
- OR1G1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61030122, COSV61030467; called by muse, mutect2, varscan2
- PCDHB2 | c.638C>A p.T213N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs376693798, COSV52035939; called by muse, mutect2, varscan2
- PDK4 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as COSV50011973; called by muse, mutect2, varscan2
- PTBP1 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as rs751656120, COSV62461315; called by muse, mutect2, varscan2
- PTPRE | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.505); catalogued as COSV54556240; called by muse, mutect2, varscan2
- RELA | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58015709; called by muse, mutect2, varscan2
- SETD2 | c.3067A>G p.S1023G | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV57446419; called by muse, mutect2, varscan2
- SHOC1 | c.2372G>C p.S791T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.382); catalogued as COSV59505673; called by muse, mutect2, varscan2
- SKIL | c.2021A>T p.Q674L | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52061767; called by muse, mutect2, varscan2
- SLC9A9 | c.1066G>T p.D356Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100339987, COSV57239226; called by muse, mutect2, varscan2
- SMPD2 | c.62A>T p.Y21F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV57806531; called by muse, mutect2, varscan2
- SNW1 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53174744; called by muse, mutect2, varscan2
- SPATA18 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV54648462; called by muse, mutect2, varscan2
- TENT5D | c.95A>T p.N32I | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57638400; called by muse, mutect2, varscan2
- TIPRL | c.519A>C p.R173S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63208040; called by muse, mutect2, varscan2
- TOPORS | c.581C>G p.S194* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as COSV62117864; called by muse, mutect2, varscan2
- TPRG1L | c.566C>G p.A189G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV54562863; called by muse, mutect2, varscan2
- TRIM41 | c.1667G>A p.G556D | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as rs867333362, COSV59320790; called by muse, mutect2, varscan2
- UBR4 | c.461T>A p.M154K | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV64395995; called by muse, mutect2, varscan2
- WWC2 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV66715616; called by muse, mutect2, varscan2
- CABS1 | c.715del p.I239* | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- EAF1 | c.789_792delinsG p.S264del | In Frame Del (DEL) | VAF 9/34 reads (26%) | called by pindel, varscan2*
- ITGA7 | c.3229_3232del p.A1077Kfs*19 (on ENST00000555728; = p.A1033Kfs*19 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- ORMDL2 | c.400_401del p.V134Tfs*57 | Frame Shift Del (DEL) | VAF 32/140 reads (23%) | called by pindel, varscan2
- RAD54B | c.1569_1570del p.G524Tfs*5 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- RNF123 | c.2513_2515del p.I838_Y839delinsN | In Frame Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- STAG2 | c.410_418del p.R137_Q140delinsK | In Frame Del (DEL) | VAF 113/372 reads (30%) | called by mutect2, pindel, varscan2
- TMEM63C | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.202); called by muse, mutect2
- TRPV6 | c.603_604del p.F202Wfs*14 | Frame Shift Del (DEL) | VAF 36/80 reads (45%) | called by mutect2, pindel, varscan2
- VCX | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.38); called by muse, mutect2
- WWC1 | c.2025_2041del p.F675Lfs*4 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- ZNF875 | c.1328G>T p.C443F | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- AMOTL1 | c.1083C>T p.V361= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54417824; called by muse, mutect2, varscan2
- CADM1 | c.226C>T p.L76= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs752868486, COSV59018855; called by muse, mutect2, varscan2
- CC2D2A | c.741T>A p.G247= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV67505101; called by muse, mutect2, varscan2
- CCT8 | c.441A>G p.V147= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as COSV54505519; called by muse, mutect2, varscan2
- CRYZL1 | c.21A>G p.Q7= | Silent (SNP) | VAF 86/242 reads (36%) | catalogued as COSV51678870; called by muse, mutect2, varscan2
- DNAH5 | c.5925G>A p.G1975= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs755312532, COSV54243443, COSV99445598; called by muse, mutect2, varscan2
- FAT1 | c.4038C>A p.I1346= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV71675398; called by muse, mutect2, varscan2
- GRAMD1A | c.426C>G p.T142= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV58768341; called by muse, mutect2, varscan2
- GRIN2A | c.2550G>A p.T850= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs750224605, COSV58020783; called by muse, mutect2, varscan2
- HEATR4 | c.2463C>A p.I821= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs747162876, COSV58374391; called by muse, mutect2, varscan2
- IFNE | c.591G>A p.K197= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV58643127; called by muse, mutect2, varscan2
- L3MBTL1 | c.1281C>T p.S427= (on ENST00000418998 / NM_001377303.1; = p.S337= on NM_015478.7) | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV64229356; called by muse, mutect2
- LHFPL2 | c.408T>C p.C136= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV66715690; called by muse, mutect2, varscan2
- MCM10 | c.1614C>G p.A538= (on ENST00000484800 / NM_182751.3; = p.A537= on NM_018518.5) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV66336055; called by muse, mutect2, varscan2
- MYBBP1A | c.3936T>G p.L1312= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV54601584; called by muse, mutect2, varscan2
- NRXN2 | c.1617G>A p.G539= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV55460449; called by muse, mutect2
- RECQL | c.726G>A p.K242= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV69659035; called by muse, mutect2
- SAMD11 | c.1623C>G p.T541= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV58990085; called by muse, mutect2, varscan2
- SUGCT | c.1041C>A p.V347= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV59345435; called by muse, mutect2, varscan2
- SYT9 | c.942T>C p.S314= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV59622966; called by muse, mutect2, varscan2
- TAAR2 | c.909T>C p.F303= (on ENST00000367931 / NM_001033080.1; = p.F258= on NM_014626.3) | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as COSV51579682; called by muse, mutect2, varscan2
- TTN | c.70077T>C p.C23359= (on ENST00000591111; = p.C15935= on NM_003319.4) | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV60245324; called by muse, mutect2, varscan2
- WDR45 | c.819C>T p.R273= (on ENST00000376372 / NM_001029896.2; = p.R274= on NM_007075.3) | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV59876658; called by muse, mutect2, varscan2
- WDR59 | c.2631G>A p.E877= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV50941188; called by muse, mutect2, varscan2
- CDCA7 | c.147+598G>T | Intron (SNP) | VAF 36/100 reads (36%) | catalogued as rs751813434, COSV60721128; called by muse, mutect2, varscan2
- FRMPD4 | c.-1C>T | 5'UTR (SNP) | VAF 27/83 reads (33%) | catalogued as COSV101043704; called by muse, mutect2, varscan2
